Somatic mutation profile of tumor specimen TCGA-DD-AADA-01A (aliquot TCGA-DD-AADA-01A-11D-A40R-10) from TCGA case TCGA-DD-AADA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 66.5 years (24,288 days).
Specimen TCGA-DD-AADA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9e02698-4222-4c0e-a0ca-815e3b01c96e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADA-10A (Blood Derived Normal), aliquot TCGA-DD-AADA-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b17b8643-a646-4139-8721-f67673c0eb05

The open-access MAF lists 130 somatic variants for this specimen: 103 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 89, Silent 27, Nonsense Mutation 4, Frame Shift Ins 3, In Frame Del 3, Frame Shift Del 2, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 21/136 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.812G>T p.R271I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV100933041; called by muse, mutect2, varscan2
- ABO | c.559del p.R187Afs*4 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | catalogued as COSV71743653; called by mutect2, pindel, varscan2
- AC006059.2 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV100045227; called by muse, mutect2, varscan2
- APBB1 | c.1059A>T p.Q353H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV100193647; called by muse, mutect2, varscan2
- AQP2 | c.434T>A p.I145N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99550744; called by muse, mutect2, varscan2
- ARHGEF28 | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99708322; called by muse, mutect2, varscan2
- ARSH | c.1385G>T p.C462F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101139760; called by muse, mutect2, varscan2
- ASB17 | c.152T>A p.L51Q | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99407823; called by muse, mutect2, varscan2
- ASXL3 | c.3626T>A p.V1209E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV52483141, COSV99323676; called by muse, mutect2, varscan2
- ATP8A1 | c.3233A>T p.K1078I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100045183; called by muse, mutect2
- BAP1 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV56240393, COSV99964331; called by muse, mutect2, varscan2
- BAP1 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 46/124 reads (37%) | catalogued as COSV56240800; called by muse, mutect2, varscan2
- CACNA1B | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs750853843, COSV53157461; called by muse, mutect2, varscan2
- CARMIL1 | c.3077T>C p.V1026A | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100277049; called by muse, mutect2, varscan2
- CCDC103 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV99493084; called by muse, mutect2, varscan2
- CCDC178 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs371081933, COSV55769182; called by muse, mutect2, varscan2
- CDH1 | c.1535A>T p.E512V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99931364; called by muse, mutect2, varscan2
- CLCN3 | c.1052G>T p.R351I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100641605; called by muse, mutect2, varscan2
- COG3 | c.1298A>T p.E433V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100596406; called by muse, mutect2, varscan2
- COL20A1 | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV58922690; called by muse, mutect2, varscan2
- CPT1A | c.1583A>T p.E528V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as COSV99680681; called by muse, mutect2, varscan2
- CYP11B1 | c.961T>A p.F321I | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as HM972175, COSV99454618; called by muse, mutect2, varscan2
- DCUN1D1 | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1416142681, COSV99489715; called by muse, mutect2
- DLL3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs781119337, COSV99218788; called by muse, mutect2
- DNAJB2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as COSV100338852; called by muse, mutect2, varscan2
- EDAR | c.1223T>C p.I408T | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104384374, COSV99303163; called by muse, mutect2
- EGFLAM | c.2087A>T p.H696L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100379919; called by mutect2, varscan2
- EMILIN3 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100182391; called by muse, mutect2, varscan2
- EML5 | c.4423G>T p.V1475F (on ENST00000380664; = p.V1483F on NM_183387.3) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100715121; called by muse, mutect2, varscan2
- EPHB6 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100844153; called by muse, mutect2, varscan2
- EPS8L1 | c.842C>T p.A281V (on ENST00000201647 / NM_133180.3; = p.A154V on NM_017729.3) | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99135519; called by muse, mutect2, varscan2
- FAT4 | c.12461C>T p.A4154V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100627395; called by muse, mutect2, varscan2
- FREM2 | c.1211A>T p.Q404L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV99747162; called by muse, mutect2, varscan2
- GATB | c.1236A>G p.I412M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99858783; called by muse, mutect2, varscan2
- GRIN1 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV59299358; called by muse, mutect2, varscan2
- GRM7 | c.1679G>A p.C560Y | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100735850; called by muse, mutect2, varscan2
- HEATR5B | c.2461G>T p.A821S | Missense Mutation (SNP) | VAF 146/355 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); catalogued as COSV99248455; called by muse, mutect2, varscan2
- HELLS | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 8/194 reads (4%) | catalogued as COSV53297964; called by muse, mutect2
- JADE1 | c.2048A>G p.K683R | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99885355; called by muse, mutect2, varscan2
- JPH2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100881616; called by muse, mutect2
- KCTD13 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774531778, COSV100442022; called by muse, mutect2, varscan2
- KHNYN | c.1766A>T p.E589V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99249444; called by muse, mutect2, varscan2
- LAMA1 | c.5624C>G p.A1875G | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101055280; called by muse, mutect2, varscan2
- LRFN2 | c.1046C>A p.T349N | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100599161; called by muse, mutect2, varscan2
- LRRIQ1 | c.1590A>T p.L530F | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV101279625; called by muse, mutect2, varscan2
- LVRN | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.266); catalogued as COSV100773353; called by muse, mutect2, varscan2
- MAP3K15 | c.2132A>T p.Q711L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100134224; called by muse, mutect2, varscan2
- MRTO4 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs139632622; called by muse, mutect2, varscan2
- NCF4 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957129; called by muse, mutect2, varscan2
- NCOA6 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV100749922; called by muse, mutect2, varscan2
- NCOR2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100656958; called by muse, mutect2, varscan2
- NNT | c.1484A>G p.N495S | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.071); catalogued as rs199609080, COSV99238477; called by muse, mutect2, varscan2
- OR10G7 | c.207G>T p.M69I | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100389788; called by muse, mutect2, varscan2
- OR1S1 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100515257; called by muse, mutect2, varscan2
- OR5D18 | c.559T>A p.S187T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV100450547; called by muse, mutect2, varscan2
- OR5K1 | c.788A>C p.N263T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.61); catalogued as COSV100220886; called by muse, mutect2, varscan2
- P2RY2 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.409); catalogued as COSV100232643; called by muse, mutect2, varscan2
- PAK3 | c.1549A>T p.M517L (on ENST00000262836 / NM_001324328.2; = p.M502L on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99456627; called by muse, mutect2, varscan2
- PAPPA2 | c.5107T>C p.W1703R | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.321); catalogued as COSV100867631; called by muse, mutect2, varscan2
- PCDHA2 | c.1563G>T p.Q521H | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100973631; called by muse, mutect2, varscan2
- PDE6A | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99677889; called by muse, mutect2, varscan2
- PLA2G4A | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 57/169 reads (34%) | catalogued as rs774762374, COSV100820410; called by muse, mutect2, varscan2
- PNMT | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.149); catalogued as COSV99510494; called by muse, mutect2
- POLQ | c.1738G>A p.G580R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs984349817, COSV99951731; called by muse, mutect2, varscan2
- PRPS1L1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101552918; called by muse, mutect2, varscan2
- PRUNE2 | c.7355G>T p.G2452V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as COSV100944263; called by muse, mutect2, varscan2
- PRX | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs752531623, COSV99397522, COSV99397940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRK | c.1897G>T p.V633F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100950474; called by muse, mutect2, varscan2
- QRFPR | c.870T>A p.H290Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781439706, COSV100543505; called by muse, mutect2, varscan2
- RCAN1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs747238292, COSV58250325; called by muse, mutect2, varscan2
- RFTN1 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV100488924; called by muse, mutect2, varscan2
- RFX7 | c.2870C>G p.A957G (on ENST00000559447 / NM_001368074.1; = p.A1054G on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100428256; called by muse, mutect2, varscan2
- RIC1 | c.3490A>G p.I1164V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99316743; called by mutect2, varscan2
- SAGE1 | c.472A>T p.N158Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100186774; called by muse, mutect2, varscan2
- SLC4A3 | c.1937T>A p.M646K | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99812491; called by muse, mutect2, varscan2
- SLC8A3 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100775965; called by muse, mutect2, varscan2
- SORCS1 | c.3418G>A p.D1140N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.052); catalogued as rs773379815, COSV99543864; called by muse, mutect2, varscan2
- SS18L1 | c.800T>G p.M267R | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); catalogued as COSV100064542; called by muse, mutect2
- TEP1 | c.5261A>G p.Q1754R | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.214); catalogued as rs111632717, COSV99401778; called by muse, mutect2, varscan2
- TLK2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 113/332 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV100408765; called by muse, mutect2, varscan2
- TMCO4 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.201); catalogued as COSV99229935; called by muse, mutect2, varscan2
- TMEM41A | c.281T>C p.L94S | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770089968, COSV99956527; called by muse, mutect2, varscan2
- TPX2 | c.1343A>T p.K448M | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100301566; called by muse, mutect2, varscan2
- TRAF1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV100875115; called by muse, mutect2, varscan2
- TRPC4AP | c.368C>G p.T123S | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99327878; called by muse, mutect2, varscan2
- TTN | c.60158A>T p.Y20053F (on ENST00000591111; = p.Y12629F on NM_003319.4) | Missense Mutation (SNP) | VAF 7/109 reads (6%) | PolyPhen benign (0.118); catalogued as COSV100597449; called by muse, mutect2
- VPS35 | c.963T>G p.D321E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV100140486; called by muse, mutect2, varscan2
- WBP1L | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100882442; called by muse, mutect2, varscan2
- WDR49 | c.295A>T p.R99W (on ENST00000308378 / NM_001366158.1; = p.R440W on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57720282; called by muse, mutect2, varscan2
- ZDBF2 | c.6371A>G p.D2124G | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100984425; called by muse, mutect2, varscan2
- ZNF536 | c.1766G>A p.G589D | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV100834791; called by muse, mutect2, varscan2
- ZNF544 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as COSV54136383; called by muse, mutect2, varscan2
- ZNF610 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100016725; called by muse, mutect2, varscan2
- ZNF791 | c.1238del p.E413Gfs*19 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as COSV58482180; called by mutect2, pindel, varscan2
- ALB | c.960_962del p.D320del | In Frame Del (DEL) | VAF 32/116 reads (28%) | called by pindel, varscan2
- KRT76 | c.1519+2del p.X507_splice | Splice Site (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- LAMB1 | c.1878dup p.A627Sfs*19 | Frame Shift Ins (INS) | VAF 13/56 reads (23%) | called by mutect2, varscan2
- MLXIPL | c.823_840del p.Y275_D280del | In Frame Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- PRKDC | c.4003_4005dup p.C1335dup | In Frame Ins (INS) | VAF 43/83 reads (52%) | called by mutect2, pindel, varscan2
- TDRD5 | c.1005dup p.L336Ifs*14 | Frame Shift Ins (INS) | VAF 30/286 reads (10%) | called by mutect2, varscan2
- TF | c.609dup p.Y204Ifs*28 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- ZNF18 | c.917_925del p.Q306_L308del | In Frame Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel
- APLP1 | c.384C>T p.C128= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as rs1385933793, COSV99383638; called by muse, mutect2
- ARHGAP39 | c.2574A>T p.A858= (on ENST00000276826 / NM_001308208.2; = p.A889= on NM_025251.2) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99430386; called by muse, mutect2, varscan2
- CACNA1G | c.2331C>A p.I777= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100661268; called by muse, mutect2
- CAMSAP3 | c.1506C>T p.P502= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1329778656, COSV99349979, COSV99351643; called by muse, mutect2, varscan2
- CRYBG1 | c.2265C>A p.V755= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV100954409; called by muse, mutect2, varscan2
- DKK1 | c.174T>C p.S58= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs887336853, COSV100906487; called by muse, mutect2, varscan2
- DPY19L2 | c.1815C>T p.L605= | Silent (SNP) | VAF 47/155 reads (30%) | catalogued as rs140003085, COSV61040807; called by muse, mutect2, varscan2
- EXO1 | c.1890G>A p.L630= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV100799635; called by muse, mutect2
- FRK | c.1314A>G p.T438= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV101606632; called by muse, mutect2, varscan2
- GNPDA2 | c.528A>T p.G176= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99776806; called by muse, mutect2, varscan2
- HMCN1 | c.10818A>T p.G3606= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs1424077436, COSV99624973; called by muse, mutect2, varscan2
- KCNV2 | c.672G>A p.A224= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV101172521; called by muse, mutect2, varscan2
- MAGI2 | c.2526C>T p.I842= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs771635003, COSV100833270, COSV100836714; called by muse, mutect2, varscan2
- MEFV | c.447C>T p.A149= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99560353, COSV99561023; called by muse, mutect2, varscan2
- MID1 | c.288T>A p.S96= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100452250; called by muse, mutect2, varscan2
- NAV2 | c.2856C>T p.S952= (on ENST00000396087 / NM_001244963.2; = p.S929= on NM_145117.5) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs199691877, COSV100216283, COSV60656854; called by mutect2, varscan2
- NID2 | c.2892C>T p.D964= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs142814187; called by muse, mutect2, varscan2
- NPC1L1 | c.3861C>T p.V1287= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs780659447, COSV99202780; called by muse, mutect2
- PCDHB1 | c.1764C>A p.T588= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs1554267422, COSV60632349; called by muse, mutect2, varscan2
- PLEKHB1 | c.462G>T p.S154= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99909435; called by mutect2, varscan2
- PREX2 | c.963A>G p.G321= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV99905419; called by mutect2, varscan2
- ROBO1 | c.2619C>T p.A873= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV101458339; called by muse, mutect2, varscan2
- SPOCK1 | c.297C>T p.T99= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99968148; called by muse, mutect2, varscan2
- VPS13D | c.2934C>T p.L978= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs1221219334, COSV99165583; called by muse, mutect2, varscan2
- WIZ | c.2688G>A p.T896= (on ENST00000673675 / NM_001371589.1; = p.T159= on NM_021241.3) | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as rs767650543, COSV99652738, COSV99653528; called by muse, mutect2, varscan2
- ZBTB12 | c.348G>A p.V116= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as COSV100976955; called by muse, mutect2, varscan2
- ZNF536 | c.1767C>A p.G589= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV100834792; called by muse, mutect2, varscan2
